Surgical pathology report (de-identified scan), TCGA case TCGA-ZF-A9RD, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of Sheffield, specimen TCGA-ZF-A9RD-01A (Primary Tumor).

SPECIMEN

Bladder and ovaries

CLINICAL DETAILS

Cystectomy and bilateral salpingo-oophorectomy for bladder cancer.

MACROSCOPY

Cystectomy specimen measuring 120 x 80 x 50mm with attached cuff of vagina and tubes and ovaries. There is a polypoid and partly ulcerated tumour in the posterior wall of the bladder and extending to the fundus, measuring 60 x 55 x 20mm. The tumour infiltrates the bladder wall, extending to the outer half of the muscle and almost reaches close to the posterior serosal surface. The serosal surface appears slightly nodular and congested. The attached right ovary measures 20 x 25 x 5mm and the fallopian tube measures 30 x 5mm. The left ovary measures 30 x 15 x 5mm and the left fallopian tube measures 40 x 5mm. The cuff of vagina measures 20 x 20 x 7mm is seen attached.

MICROSCOPY

The bladder shows solid grade 3 transitional cell carcinoma with extensive squamous differentiation. The tumour infiltrates full thickness of the muscle and extends focally into perivesical fat. No lymphovascular invasion is noted. There is focal necrosis within the tumour. The background urothelium shows possible dysplasia in some areas, no carcinoma in situ is seen. The attached fallopian tubes, ovaries and the vaginal cuff are within normal histological limits.

4 lymph nodes were dissected out from the perivesical fat, one of which shows metastatic tumour deposit. (Please see also report number accompanying lymph node dissection).

SUMMARY

Cystectomy and bilateral salpingo-oophorectomy -

Grade 3 transitional cell carcinoma with extensive squamous differentiation

pT3a N2 Mx (staging takes into account lymph nodes received separately - report number ; total number of positive lymph nodes in both specimens 5/15)

Pathologists -

Dr
DR

ICD-O-3

CGCF
(carcinoma) urothelial NOS 8120/3
path
(carcinoma), transitional cell & squamous
cell
8120/3
Code to highest 8120/3
Site 4 Bladder, posterior wall C67.4

Criteria:	W 3/21/14	Yes	No

Source: NCI Genomic Data Commons file 8969bef7-9486-4411-aedb-2ad966e9c5bc (TCGA-ZF-A9RD.6B721B6B-AD81-422E-8390-D615EA75EF64.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).